Somatic mutation profile of tumor specimen TCGA-12-0616-01A (aliquot TCGA-12-0616-01A-01D-1492-08) from TCGA case TCGA-12-0616, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 36.8 years (13,451 days).
Specimen TCGA-12-0616-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0d2a386-804a-4080-a911-fc642c19b5e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0616-10A (Blood Derived Normal), aliquot TCGA-12-0616-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/646aef9e-a618-43e7-8b1e-277cda66efac

The open-access MAF lists 40 somatic variants for this specimen: 27 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 12, Splice Site 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 336/1096 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.123); catalogued as rs372285217; called by muse, mutect2, varscan2
- ADCY10 | c.3077+1G>A p.X1026_splice | Splice Site (SNP) | VAF 43/121 reads (36%) | catalogued as COSV63239015; called by muse, mutect2, varscan2
- ADGRV1 | c.16745C>T p.T5582M | Missense Mutation (SNP) | VAF 121/394 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as rs771468922, COSV67980150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG3 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV50064715; called by muse, mutect2, varscan2
- DCAF12L1 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV64421302; called by muse, mutect2, varscan2
- DMRTB1 | c.994C>G p.P332A | Missense Mutation (SNP) | VAF 124/438 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.283); catalogued as COSV65112753; called by muse, mutect2, varscan2
- FDPS | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs749581999, COSV63113996; called by muse, mutect2, varscan2
- FRYL | c.3964A>C p.K1322Q | Missense Mutation (SNP) | VAF 36/415 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV51942017; called by muse, mutect2
- GAD1 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64025169; called by muse, mutect2, varscan2
- HAUS7 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as COSV57848148; called by muse, mutect2, varscan2
- HUWE1 | c.9611G>A p.R3204H | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53337879; called by muse, mutect2, varscan2
- IGHV3-74 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); catalogued as rs769025914; called by muse, mutect2
- LPAR5 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV61692081; called by muse, mutect2, varscan2
- MMP12 | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as COSV100404953, COSV58259346; called by muse, mutect2, varscan2
- NCKAP5 | c.2684C>T p.S895L | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1226731934, COSV58432613; called by muse, varscan2
- NOC4L | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1481439440, COSV57957542; called by muse, mutect2
- OR52M1 | c.262T>C p.W88R | Missense Mutation (SNP) | VAF 77/122 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64171591; called by muse, mutect2, varscan2
- OR56A3 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 151/216 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs957219841, COSV61568454; called by muse, mutect2, varscan2
- OR8H2 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 77/474 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs773811836, COSV100542430, COSV57943654; called by muse, mutect2, varscan2
- PCCA | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66189212; called by muse, mutect2, varscan2
- SF3B2 | c.2015A>G p.K672R | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as COSV59427319; called by muse, mutect2, varscan2
- SRSF11 | c.623C>G p.P208R | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100917792, COSV63936733; called by muse, mutect2, varscan2
- TRRAP | c.2935G>C p.D979H | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62840855; called by muse, mutect2, varscan2
- TTC39A | c.865G>A p.V289M (on ENST00000447632 / NM_001297665.1; = p.V254M on NM_001080494.3) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as rs777724015, COSV52956992; called by muse, mutect2, varscan2
- VIT | c.1348G>A p.V450M (on ENST00000389975 / NM_001177969.1; = p.V465M on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775954409, COSV64895612; called by muse, mutect2, varscan2
- DNAH1 | c.7180dup p.S2394Kfs*61 | Frame Shift Ins (INS) | VAF 69/210 reads (33%) | called by mutect2, pindel, varscan2
- CASR | c.900C>T p.A300= | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as COSV56135311; called by muse, mutect2, varscan2
- CELSR1 | c.5667C>T p.D1889= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs549063106, COSV53085308; called by muse, mutect2, varscan2
- DLX3 | c.48C>T p.I16= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as COSV71547546; called by muse, mutect2, varscan2
- FRMD3 | c.390T>C p.L130= | Silent (SNP) | VAF 9/159 reads (6%) | catalogued as rs1290069081, COSV58456318; called by muse, mutect2
- KIT | c.1404G>A p.P468= | Silent (SNP) | VAF 53/130 reads (41%) | catalogued as rs767079772, COSV55392133; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEC1 | c.2055G>A p.G685= | Silent (SNP) | VAF 89/249 reads (36%) | catalogued as rs1442238301, COSV53569450; called by muse, mutect2, varscan2
- NEB | c.9828T>C p.S3276= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV50845921; called by muse, mutect2, varscan2
- NPAS3 | c.2616C>T p.L872= (on ENST00000356141 / NM_001164749.2; = p.L840= on NM_022123.3) | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV60825220; called by muse, mutect2, varscan2
- PHTF2 | c.1050G>A p.V350= (on ENST00000248550 / NM_001366089.1; = p.V312= on NM_020432.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV50324209; called by muse, mutect2, varscan2
- S100A7A | c.249C>T p.A83= | Silent (SNP) | VAF 51/116 reads (44%) | catalogued as rs770816797, COSV61330083; called by muse, mutect2, varscan2
- SURF4 | c.648C>T p.N216= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as rs371493854; called by muse, mutect2, varscan2
- TMEM63A | c.1843C>T p.L615= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs1469368597, COSV64762605; called by muse, mutect2
- OR3A4P | n.1249C>T | RNA (SNP) | VAF 70/170 reads (41%) | catalogued as rs758506070; called by muse, mutect2, varscan2
